TCGA case TCGA-C5-A7CL — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Medical College of Wisconsin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bae2af5e-484a-44f7-ad6b-66137cdae300

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 48 years; Vital status: Dead; Days to death: 471 days (1.3 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 48.9 years (17,869 days); Year of diagnosis: 2002; Method of diagnosis: Biopsy; FIGO stage: Stage IIIB; FIGO staging edition year: 1995; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 27 days; Treatment dose: 61 Gy; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, Internal; Days to treatment start: 27 days; Treatment dose: 650 cGy; Number of fractions: 6.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 35 days; Days to treatment end: 77 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative.

Follow-up (1 entry)
- Days to follow up: 471 days (1.3 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Stillbirth.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 3; Pregnancy outcome: Live Birth.
- Timepoint category: Initial Diagnosis; Weight: 103 kg; Height: 163 cm; BMI: 38.8.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Induced Abortion.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Ectopic Pregnancy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Miscarriage.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 20; Age at onset: 29.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-C5-A7CL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 60 mg.
  Slide TCGA-C5-A7CL-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-C5-A7CL-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-C5-A7CL-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 3; Pregnancies count miscarriage: 0; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Total pregnancy count: 3; Tobacco smoking history indicator: 2; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Cause of death: Cervical Cancer; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 471 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 471 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 471 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-C5-A7CL-01A-11D-A32H-01): tumor purity 0.63, ploidy 2.01, whole-genome doublings 0.
